Somatic mutation profile of tumor specimen ALCH-B34H-TTP1-A (aliquot ALCH-B34H-TTP1-A-1-0-D-A78R-36) from ALCHEMIST case ALCH-B34H, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 77.2 years (28,182 days).
Specimen ALCH-B34H-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da35f521-fdef-4bc0-97bc-b51b82de345c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B34H-NB1-A (Blood Derived Normal), aliquot ALCH-B34H-NB1-A-1-0-D-A78R-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aef670cf-7588-4de2-8e7c-aa5c1448ee81

The open-access MAF lists 39 somatic variants for this specimen: 24 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 12, Splice Site 3, Intron 3, Nonsense Mutation 2, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARRDC1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 25/244 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV58382924; called by muse, mutect2, varscan2
- NOC2L | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 30/311 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs1359441783; called by muse, mutect2, varscan2
- OLFM2 | c.1088C>A p.T363N | Missense Mutation (SNP) | VAF 33/389 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53428860; called by muse, mutect2
- RPGRIP1L | c.1357G>C p.D453H | Missense Mutation (SNP) | VAF 19/202 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV50915263; called by muse, mutect2
- SIN3B | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 27/292 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1389356208; called by muse, mutect2
- AGTPBP1 | c.3662C>G p.S1221* (on ENST00000357081 / NM_001330701.2; = p.S1181* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | called by muse, mutect2
- CMTR2 | c.1949dup p.C650Wfs*18 | Frame Shift Ins (INS) | VAF 14/60 reads (23%) | called by mutect2, pindel, varscan2
- COL4A3 | c.3500G>A p.G1167E | Missense Mutation (SNP) | VAF 54/469 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DNAH6 | c.389_390insCAAAATGCAGGTATAAT p.K130Nfs*6 | Nonsense Mutation (INS) | VAF 8/94 reads (9%) | called by muse*, mutect2
- FOXC2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRS3 | c.847C>G p.P283A | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.095); called by muse, mutect2
- GBP1 | c.763G>C p.D255H | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2
- HAT1 | c.171T>G p.H57Q | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HLA-DRA | c.706del p.I236Sfs*29 | Frame Shift Del (DEL) | VAF 9/71 reads (13%) | called by mutect2, pindel, varscan2
- IKBKB | c.1987-2A>T p.X663_splice | Splice Site (SNP) | VAF 17/158 reads (11%) | called by muse, mutect2, varscan2
- KRTAP25-1 | c.243C>A p.S81R | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.72); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- LTBP3 | c.3629-1G>C p.X1210_splice (on ENST00000301873 / NM_001130144.3; = p.X1163_splice on NM_021070.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 46/529 reads (9%) | called by muse, mutect2
- NEB | c.2107-6_2108del p.X703_splice | Splice Site (DEL) | VAF 11/82 reads (13%) | called by mutect2, pindel, varscan2
- SNX29 | c.485C>G p.P162R | Missense Mutation (SNP) | VAF 28/494 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPICE1 | c.1771C>G p.Q591E | Missense Mutation (SNP) | VAF 16/277 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.167); called by muse, mutect2
- TFCP2 | c.1184G>T p.C395F | Missense Mutation (SNP) | VAF 16/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- TOP2B | c.695G>C p.G232A (on ENST00000264331 / NM_001330700.2; = p.G227A on NM_001068.3) | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.45); called by muse, mutect2
- TRAK2 | c.2462C>T p.S821F | Missense Mutation (SNP) | VAF 33/290 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- WASHC5 | c.2649G>C p.M883I | Missense Mutation (SNP) | VAF 42/333 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ETS2 | c.366C>T p.F122= | Silent (SNP) | VAF 14/300 reads (5%) | catalogued as rs771567210; called by muse, mutect2
- EXOC3 | c.540G>T p.T180= | Silent (SNP) | VAF 42/278 reads (15%) | called by muse, mutect2, varscan2
- LOXHD1 | c.952T>C p.L318= | Silent (SNP) | VAF 45/302 reads (15%) | catalogued as rs1201159540; called by muse, mutect2, varscan2
- MCAM | c.576G>A p.S192= | Silent (SNP) | VAF 21/222 reads (9%) | catalogued as rs191220491, COSV50662731; called by muse, mutect2, varscan2
- PHF8 | c.1002C>T p.D334= (on ENST00000357988 / NM_001184896.1; = p.D298= on NM_015107.3) | Silent (SNP) | VAF 28/279 reads (10%) | called by muse, mutect2, varscan2
- PODN | c.1851G>C p.R617= (on ENST00000395871; = p.R569= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/106 reads (12%) | called by mutect2, varscan2
- PTPRA | c.1296T>G p.P432= | Silent (SNP) | VAF 28/210 reads (13%) | called by muse, mutect2, varscan2
- REG1A | c.102C>A p.I34= | Silent (SNP) | VAF 46/398 reads (12%) | catalogued as COSV52071046; called by muse, mutect2, varscan2
- SOS1 | c.2043T>C p.Y681= | Silent (SNP) | VAF 48/304 reads (16%) | catalogued as rs1466930017; called by muse, mutect2
- SSTR3 | c.783C>T p.A261= | Silent (SNP) | VAF 18/210 reads (9%) | catalogued as rs144127697, COSV100142923; called by muse, mutect2
- STAG2 | c.759T>C p.N253= | Silent (SNP) | VAF 39/255 reads (15%) | called by muse, mutect2, varscan2
- TMPO | c.48G>A p.L16= | Silent (SNP) | VAF 44/630 reads (7%) | called by muse, mutect2
- BPIFB1 | c.662-760G>C | Intron (SNP) | VAF 33/257 reads (13%) | called by muse, mutect2, varscan2
- EIF2AK1 | c.450-151G>A | Intron (SNP) | VAF 6/89 reads (7%) | catalogued as rs1434530928; called by muse, mutect2
- HCFC1R1 | c.95+19G>A | Intron (SNP) | VAF 56/241 reads (23%) | catalogued as rs374090448; called by muse, mutect2, varscan2
